Surgical pathology report (de-identified scan), TCGA case TCGA-22-5473, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5473-01A (Primary Tumor).

DIAGNOSIS:

Lung, left lower, lobectomy: Invasive grade 3 (of 4) squamous cell carcinoma forming an 8.0 x 5.8 x 5.5 cm mass 3.5 cm from the bronchial margin. Tumor infiltrates visceral pleura but does not extend to the free pleural surface. Surgical margins, including bronchial margin are negative for tumor. Multiple (8) intrapulmonary peribronchial lymph nodes are negative for tumor.

Lymph nodes, mediastinal, excision:

- No tumor is identified in multiple (4) right upper paratracheal (station 2R) lymph nodes.
- No tumor is identified in multiple (5) right lower paratracheal (station 4R) lymph nodes.
- No tumor is identified in multiple (4) left lower paratracheal (station 4L) lymph nodes.
- No tumor is identified in a single subaortic (station 5) lymph node.
- No tumor is identified in multiple (7) subcarinal (station 7) lymph nodes.
- No tumor is identified in multiple (2) right pulmonary ligament (station 9R) lymph nodes.

Lymph node, intrapulmonary/hilar, excision:

- No tumor is identified in a single interlobar (station 11) lymph node.

Source: NCI Genomic Data Commons file 857c846f-52ed-49ab-ba39-dd94c1750370 (TCGA-22-5473.12973D4A-4C25-43DC-920B-D32407D45461.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).